Somatic mutation profile of tumor specimen C3L-06174-01 (aliquot CPT0456420009) from CPTAC case C3L-06174, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 71.6 years (26,148 days).
Specimen C3L-06174-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfa456a8-d9ce-45b5-b2d2-4f20161fe4c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06174-31 (Blood Derived Normal), aliquot CPT0456570005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e99a4be-62f7-4db4-8f5f-690929954e03

The open-access MAF lists 128 somatic variants for this specimen: 86 protein-altering or splice-affecting, 36 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 36, Nonsense Mutation 6, Frame Shift Del 3, Intron 3, 3'Flank 2, Frame Shift Ins 1, Translation Start Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2305G>T p.D769Y | Missense Mutation (SNP) | VAF 50/381 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913468, COSV54062373, COSV54062425, COSV54063143; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMAD3 | c.277C>T p.R93* | Nonsense Mutation (SNP) | VAF 164/594 reads (28%) | catalogued as rs768713596, COSV59284932; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.1829A>C p.K610T | Missense Mutation (SNP) | VAF 44/409 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs202020248; called by muse, mutect2, varscan2
- ATRX | c.1529C>G p.S510C | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.498); catalogued as rs782395967, COSV64873031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C22orf31 | c.101C>T p.S34L | Missense Mutation (SNP) | VAF 59/482 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.343); catalogued as rs1455866103; called by muse, mutect2, varscan2
- CACNA1I | c.2803C>T p.R935* | Nonsense Mutation (SNP) | VAF 24/748 reads (3%) | catalogued as COSV60819999; called by muse, mutect2
- CAVIN2 | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 54/586 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571084497; called by muse, mutect2
- CCDC180 | c.2746C>T p.R916W | Missense Mutation (SNP) | VAF 48/632 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs747084324; called by muse, mutect2
- DNAH2 | c.5437G>A p.V1813I | Missense Mutation (SNP) | VAF 92/569 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs754083186, COSV66728727; called by muse, mutect2, varscan2
- DSCAM | c.1477G>A p.V493I | Missense Mutation (SNP) | VAF 49/323 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.37); catalogued as rs779687016, COSV104434826; called by muse, mutect2, varscan2
- ENDOD1 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 61/489 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs957695086, COSV53590151, COSV53590695; called by muse, mutect2, varscan2
- FBRS | c.1369C>T p.R457W (on ENST00000287468; = p.R977W on NM_001105079.3) | Missense Mutation (SNP) | VAF 80/571 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as rs536695874; called by muse, mutect2, varscan2
- FBXL7 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 76/635 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs939193934, COSV100309652; called by muse, mutect2, varscan2
- FGF14 | c.390A>C p.E130D | Missense Mutation (SNP) | VAF 37/335 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as COSV65942649; called by muse, mutect2, varscan2
- GREM2 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 69/530 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs1486301591, COSV58954422; called by muse, varscan2
- GRHL3 | c.1249C>T p.R417W (on ENST00000350501 / NM_198174.3; = p.R422W on NM_021180.3) | Missense Mutation (SNP) | VAF 64/407 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs993460632, COSV99359291; called by muse, mutect2, varscan2
- GRIK1 | c.59C>A p.A20E | Missense Mutation (SNP) | VAF 51/453 reads (11%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV100517459; called by muse, mutect2, varscan2
- HDGFL1 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 63/514 reads (12%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.073); catalogued as rs768895810; called by muse, mutect2, varscan2
- KCNB2 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 74/543 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs770363006, COSV73050496; called by muse, mutect2, varscan2
- KDM6B | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 48/445 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.325); catalogued as rs1343199908; called by muse, mutect2, varscan2
- LHFPL6 | c.136A>T p.T46S | Missense Mutation (SNP) | VAF 63/661 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.022); catalogued as COSV65445791; called by muse, mutect2
- LRP1B | c.4490A>G p.K1497R | Missense Mutation (SNP) | VAF 69/475 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV101255116, COSV67192589; called by muse, mutect2, varscan2
- LRRTM4 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 64/427 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as rs754661109, COSV101297751, COSV69141392, COSV69142654; called by muse, mutect2, varscan2
- MAPK10 | c.845C>T p.A282V (on ENST00000359221 / NM_001351625.2; = p.A320V on NM_002753.5) | Missense Mutation (SNP) | VAF 42/356 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs757125320, COSV60380345; called by muse, varscan2
- MPP5 | c.1778A>G p.Y593C | Missense Mutation (SNP) | VAF 44/368 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs767776735; called by muse, mutect2
- NBPF11 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 48/402 reads (12%) | catalogued as rs199498940; called by muse, mutect2, varscan2
- NEB | c.14864G>A p.R4955H | Missense Mutation (SNP) | VAF 40/367 reads (11%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.997); catalogued as rs767200761; called by muse, mutect2, varscan2
- NELL2 | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 45/372 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs139227921; called by muse, mutect2, varscan2
- NKAPL | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 75/514 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1473256908, COSV59197224; called by muse, mutect2, varscan2
- NOTCH2 | c.3143G>A p.R1048H | Missense Mutation (SNP) | VAF 49/334 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs142831890; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- NRXN1 | c.3125T>G p.L1042R | Missense Mutation (SNP) | VAF 18/536 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV58435853; called by muse, mutect2
- OGDHL | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 35/274 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs780288193, COSV65104236; called by muse, mutect2, varscan2
- OR1A2 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 79/536 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs775857630, COSV67936143; called by muse, mutect2, varscan2
- OR5W2 | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 56/413 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV60614668; called by muse, mutect2, varscan2
- PCDHA13 | c.1928C>T p.P643L | Missense Mutation (SNP) | VAF 93/565 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as COSV56510869; called by muse, mutect2, varscan2
- PGK2 | c.933G>C p.W311C | Missense Mutation (SNP) | VAF 64/505 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as COSV59164753; called by muse, mutect2, varscan2
- PPP1R26 | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 58/400 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs775254669; called by muse, mutect2, varscan2
- PPP2R1A | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 70/490 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1362406458, COSV59043527, COSV59046639; called by muse, mutect2, varscan2
- RPS27AP5 | c.27G>A p.M9I | Missense Mutation (SNP) | VAF 36/375 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1180965028; called by muse, mutect2, varscan2
- SLC13A1 | c.716T>G p.L239R | Missense Mutation (SNP) | VAF 19/444 reads (4%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.878); catalogued as COSV52014805, COSV99521317, COSV99521640; called by muse, mutect2
- SLC1A6 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 59/519 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as rs781551972, COSV55671318, COSV55675054; called by muse, mutect2, varscan2
- SLC22A3 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 66/472 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs751076718, COSV99034360; called by muse, mutect2, varscan2
- SLC43A1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 42/353 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.051); catalogued as rs201650859, COSV53558476; called by muse, mutect2, varscan2
- SMAD2 | c.929G>A p.R310K | Missense Mutation (SNP) | VAF 119/450 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100053454, COSV51053915; called by muse, mutect2, varscan2
- SPEG | c.8989G>A p.V2997M | Missense Mutation (SNP) | VAF 92/683 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs989465855, COSV56678062; called by muse, mutect2, varscan2
- SSRP1 | c.1684C>T p.R562* | Nonsense Mutation (SNP) | VAF 73/533 reads (14%) | catalogued as rs1198818327, COSV53481842; called by muse, mutect2, varscan2
- TBC1D9B | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 78/631 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs760439963, COSV62282475, COSV62284460; called by muse, mutect2, varscan2
- TUBA3D | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 101/766 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.114); catalogued as rs771254070, COSV58311955; called by muse, mutect2, varscan2
- ZBTB7C | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 85/314 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs762487158; called by muse, mutect2, varscan2
- ZFHX4 | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 71/558 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.017); catalogued as rs1218726795, COSV50479906; called by muse, mutect2, varscan2
- ZFHX4 | c.4111C>T p.P1371S | Missense Mutation (SNP) | VAF 67/517 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50511578; called by muse, mutect2, varscan2
- ZNF696 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 111/759 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs1316134823, COSV57524823, COSV57525140; called by muse, mutect2, varscan2
- ZRANB1 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 56/457 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs375457744; called by muse, mutect2, varscan2
- ZSCAN2 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 139/532 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.497); catalogued as rs762700700, COSV57572134; called by muse, mutect2, varscan2
- BHLHE40 | c.424_428dup p.G145Afs*24 | Frame Shift Ins (INS) | VAF 44/350 reads (13%) | called by mutect2, varscan2
- CACNA1A | c.6398T>C p.V2133A | Missense Mutation (SNP) | VAF 109/684 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRISPLD1 | c.102A>C p.K34N | Missense Mutation (SNP) | VAF 63/540 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CWC25 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 54/395 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- DNAH12 | c.1384C>T p.Q462* | Nonsense Mutation (SNP) | VAF 53/372 reads (14%) | called by muse, mutect2, varscan2
- E2F8 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 59/493 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- EPHA3 | c.232C>A p.Q78K | Missense Mutation (SNP) | VAF 48/394 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- GNA13 | c.136A>T p.K46* | Nonsense Mutation (SNP) | VAF 57/563 reads (10%) | called by muse, mutect2, varscan2
- GOLGA8M | c.953T>C p.V318A | Missense Mutation (SNP) | VAF 27/304 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- HNRNPD | c.125_149del p.G42Efs*52 | Frame Shift Del (DEL) | VAF 92/834 reads (11%) | called by mutect2, pindel
- HRNR | c.1906C>T p.H636Y | Missense Mutation (SNP) | VAF 88/1269 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ITPR3 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 42/382 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ14 | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 18/564 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2
- KHDRBS2 | c.720A>T p.R240S | Missense Mutation (SNP) | VAF 75/533 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- MAP2K7 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 45/320 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MRTFA | c.2866C>A p.H956N | Missense Mutation (SNP) | VAF 67/606 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- MXRA5 | c.7444G>A p.E2482K | Missense Mutation (SNP) | VAF 67/278 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NDEL1 | c.840A>T p.Q280H | Missense Mutation (SNP) | VAF 45/441 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- PARS2 | c.47C>T p.T16I | Missense Mutation (SNP) | VAF 57/476 reads (12%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH10 | c.1557C>A p.N519K | Missense Mutation (SNP) | VAF 63/502 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCLO | c.11533A>G p.T3845A | Missense Mutation (SNP) | VAF 64/508 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PIH1D2 | c.399G>T p.M133I | Missense Mutation (SNP) | VAF 38/324 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- PMIS2 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 63/466 reads (14%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- PSG7 | c.1249A>T p.T417S | Missense Mutation (SNP) | VAF 38/494 reads (8%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.005); called by muse, mutect2
- SNX25 | c.1460A>C p.E487A | Missense Mutation (SNP) | VAF 41/307 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SYNM | c.4368_4377del p.K1456Nfs*8 | Frame Shift Del (DEL) | VAF 141/536 reads (26%) | called by mutect2, pindel, varscan2
- THSD7B | c.164A>G p.D55G | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- TSHZ3 | c.2555A>G p.K852R | Missense Mutation (SNP) | VAF 61/494 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TUSC1 | c.325A>T p.S109C | Missense Mutation (SNP) | VAF 79/652 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- XYLB | c.913_914del p.L305Vfs*21 | Frame Shift Del (DEL) | VAF 36/370 reads (10%) | called by mutect2, pindel, varscan2
- ZNF461 | c.1571C>A p.P524H | Missense Mutation (SNP) | VAF 32/418 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2
- ZNF461 | c.390A>C p.E130D | Missense Mutation (SNP) | VAF 59/449 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ANK3 | c.4608G>A p.P1536= | Silent (SNP) | VAF 57/431 reads (13%) | catalogued as rs374011694; called by muse, mutect2, varscan2
- ARHGAP27 | c.1092C>T p.P364= (on ENST00000428638 / NM_001282290.1; = p.P23= on NM_199282.3) | Silent (SNP) | VAF 84/581 reads (14%) | catalogued as COSV100976620; called by muse, mutect2, varscan2
- BARHL2 | c.240C>T p.D80= | Silent (SNP) | VAF 85/669 reads (13%) | catalogued as COSV64981651; called by muse, mutect2, varscan2
- BPIFB2 | c.750C>T p.T250= | Silent (SNP) | VAF 62/567 reads (11%) | catalogued as rs370240092; called by muse, mutect2, varscan2
- CBY2 | c.559C>A p.R187= | Silent (SNP) | VAF 80/646 reads (12%) | catalogued as COSV100137936; called by muse, mutect2, varscan2
- CYP2D6 | c.1071T>A p.T357= | Silent (SNP) | VAF 97/830 reads (12%) | catalogued as rs1205858450; called by muse, mutect2, varscan2
- DCBLD1 | c.1554C>T p.I518= | Silent (SNP) | VAF 35/316 reads (11%) | called by muse, mutect2, varscan2
- DYSF | c.2016C>T p.I672= | Silent (SNP) | VAF 53/388 reads (14%) | catalogued as rs746480529, COSV50336798; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- FBXL14 | c.567C>T p.H189= | Silent (SNP) | VAF 85/525 reads (16%) | called by muse, mutect2, varscan2
- GAB1 | c.1503A>C p.P501= | Silent (SNP) | VAF 69/469 reads (15%) | called by muse, mutect2, varscan2
- GFPT2 | c.498G>A p.T166= | Silent (SNP) | VAF 42/367 reads (11%) | catalogued as rs766171030, COSV53808879; called by muse, mutect2, varscan2
- GPX4 | c.525C>T p.C175= | Silent (SNP) | VAF 75/515 reads (15%) | catalogued as rs766841959; called by muse, mutect2, varscan2
- GSX1 | c.276C>T p.H92= | Silent (SNP) | VAF 106/887 reads (12%) | called by muse, mutect2, varscan2
- HLA-G | c.180C>T p.F60= | Silent (SNP) | VAF 53/419 reads (13%) | catalogued as rs777353157, COSV64406597; called by muse, mutect2, varscan2
- IGSF10 | c.4734A>G p.K1578= | Silent (SNP) | VAF 44/632 reads (7%) | called by muse, mutect2
- INSYN2A | c.597G>A p.P199= | Silent (SNP) | VAF 99/580 reads (17%) | catalogued as rs370957941; called by muse, mutect2, varscan2
- IRAK3 | c.108C>T p.D36= | Silent (SNP) | VAF 12/392 reads (3%) | catalogued as rs1278611360; called by muse, mutect2
- IRX2 | c.132G>A p.A44= | Silent (SNP) | VAF 85/556 reads (15%) | called by muse, mutect2, varscan2
- KEL | c.1935G>A p.A645= | Silent (SNP) | VAF 48/411 reads (12%) | catalogued as rs766053821; called by muse, mutect2, varscan2
- LRRC17 | c.486C>T p.D162= | Silent (SNP) | VAF 48/460 reads (10%) | called by muse, mutect2, varscan2
- MYO16 | c.5073G>A p.A1691= | Silent (SNP) | VAF 58/490 reads (12%) | called by muse, mutect2, varscan2
- NEXMIF | c.4410A>G p.E1470= | Silent (SNP) | VAF 58/240 reads (24%) | called by muse, mutect2, varscan2
- NOVA2 | c.732G>A p.A244= | Silent (SNP) | VAF 103/680 reads (15%) | catalogued as COSV54356309; called by muse, mutect2, varscan2
- OR1E2 | c.108T>C p.L36= | Silent (SNP) | VAF 78/603 reads (13%) | catalogued as rs752546778; called by muse, mutect2
- OR9A4 | c.471C>A p.I157= | Silent (SNP) | VAF 48/653 reads (7%) | catalogued as COSV71886116; called by muse, mutect2
- PTPRA | c.1770C>T p.N590= | Silent (SNP) | VAF 38/361 reads (11%) | catalogued as rs145212464; called by muse, mutect2, varscan2
- RASA2 | c.1005A>G p.K335= | Silent (SNP) | VAF 13/284 reads (5%) | called by muse, mutect2
- ROR2 | c.1803G>A p.A601= | Silent (SNP) | VAF 79/523 reads (15%) | catalogued as rs570706687, COSV100995831; called by muse, varscan2
- SDK2 | c.1374C>A p.G458= | Silent (SNP) | VAF 65/532 reads (12%) | called by muse, mutect2, varscan2
- SEPTIN12 | c.228G>A p.K76= | Silent (SNP) | VAF 62/465 reads (13%) | called by muse, mutect2, varscan2
- SFI1 | c.3222G>A p.P1074= (on ENST00000400288 / NM_001007467.3; = p.P1043= on NM_014775.4) | Silent (SNP) | VAF 88/736 reads (12%) | catalogued as rs940932506; called by muse, varscan2
- SHANK3 | c.2124C>T p.D708= | Silent (SNP) | VAF 54/350 reads (15%) | catalogued as rs543497031; called by muse, mutect2, varscan2
- SOGA1 | c.2775G>A p.Q925= | Silent (SNP) | VAF 43/378 reads (11%) | called by muse, mutect2, varscan2
- SOX9 | c.783G>A p.E261= | Silent (SNP) | VAF 72/565 reads (13%) | catalogued as rs751690259; called by muse, mutect2, varscan2
- ZNF556 | c.624C>T p.C208= | Silent (SNP) | VAF 65/452 reads (14%) | catalogued as rs371742740; called by muse, mutect2, varscan2
- ZNHIT6 | c.1092A>G p.V364= | Silent (SNP) | VAF 31/208 reads (15%) | called by muse, mutect2
- ABI3BP | c.1577-16697C>T | Intron (SNP) | VAF 39/305 reads (13%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81156876 C>T | 3'Flank (SNP) | VAF 46/333 reads (14%) | catalogued as rs544781440; called by muse, mutect2, varscan2
- ACSF2 | c.128+555A>C | Intron (SNP) | VAF 21/500 reads (4%) | called by muse, mutect2
- ARHGAP22 | c.989-141G>A | Intron (SNP) | VAF 75/619 reads (12%) | catalogued as rs1339044217; called by muse, mutect2, varscan2
- CDCP2 | chr1:54136695 C>T | 3'Flank (SNP) | VAF 73/486 reads (15%) | catalogued as rs1456451062; called by muse, mutect2, varscan2
- PRR12 | chr19:49594509 C>T | 5'Flank (SNP) | VAF 82/572 reads (14%) | catalogued as rs761696004; called by muse, mutect2, varscan2
